Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A966, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A966-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

Tumor: 4.0 x 3.0 x 1.0 cm

Infiltration of lung parenchyma

Diagnosis:

Thymic carcinoma

pT3

Masaoka: III

Immunohistochemistry

epithelial cells positive for: CK5/6, CK18, CD5, CD117, p63

epithelial cells negative for: CD1a, CD56, chromogranin A, synaptophysin, CK7,
TTF1

Ki-67: 70-80%

No CD1a-positive T-lymphocytes

Thymoma NOS malignant
858613
Site Thymus C37.9
Q5417114

Source: NCI Genomic Data Commons file 3b5de8fe-041d-4c17-a589-720325fef9af (TCGA-ZB-A966.8C001ED3-2EF9-4DD5-9747-82A5BEE70A56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).